Somatic mutation profile of tumor specimen TARGET-30-PASGUT-01A (aliquot TARGET-30-PASGUT-01A-01D) from TARGET case TARGET-30-PASGUT, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 3.4 years (1,259 days).
Specimen TARGET-30-PASGUT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac7abb31-158a-4fe2-8d95-f4ee6a1070c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASGUT-10A (Blood Derived Normal), aliquot TARGET-30-PASGUT-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78a30893-321a-4751-9824-2f5b2b790aba

The open-access MAF lists 49 somatic variants for this specimen: 41 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 6, Intron 1, In Frame Del 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB1 | c.961G>C p.V321L | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV55953269; called by muse, mutect2, varscan2
- ANKRD36B | c.872C>T p.S291F | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as COSV51533101; called by muse, mutect2, varscan2
- CADPS2 | c.1744G>T p.V582F | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV57366715; called by muse, mutect2, varscan2
- CCT6A | c.963G>T p.M321I | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.159); catalogued as COSV51906027; called by muse, mutect2, varscan2
- CD4 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV50591603; called by muse, mutect2, varscan2
- CNTRL | c.4610G>T p.S1537I | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV53048128; called by muse, mutect2, varscan2
- COL4A3 | c.3331C>T p.L1111F | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.7); PolyPhen benign (0.328); catalogued as COSV100516746, COSV59258235; called by muse, mutect2, varscan2
- CR2 | c.1795G>T p.A599S | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV65508031; called by muse, mutect2, varscan2
- CREB5 | c.449C>T p.T150I (on ENST00000357727 / NM_182898.4; = p.T143I on NM_004904.3) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV63222157, COSV63231186; called by muse, mutect2
- DNAH5 | c.8265C>A p.F2755L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV54230658; called by muse, mutect2, varscan2
- ENTPD6 | c.1348G>A p.V450M | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as rs775848233, COSV61751663; called by muse, mutect2, varscan2
- FAM135B | c.3325G>C p.E1109Q | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.05); catalogued as COSV52715976, COSV52730387; called by muse, mutect2, varscan2
- FBXO9 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55056082; called by muse, mutect2, varscan2
- GCM1 | c.832G>T p.D278Y | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.671); catalogued as COSV52522278; called by muse, mutect2, varscan2
- IFNAR1 | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV54252386; called by muse, mutect2, varscan2
- IQSEC3 | c.1396G>C p.D466H (on ENST00000538872 / NM_001170738.2; = p.D163H on NM_015232.1) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.125); catalogued as COSV58285851; called by muse, mutect2
- ISL1 | c.115C>T p.H39Y | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57934004; called by muse, mutect2, varscan2
- LRBA | c.2491C>A p.Q831K | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.833); catalogued as COSV63956812, COSV63960624; called by muse, mutect2, varscan2
- MN1 | c.377C>T p.S126L | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100179703, COSV56559005; called by muse, mutect2, varscan2
- MORN4 | c.182+1G>C p.X61_splice | Splice Site (SNP) | VAF 49/122 reads (40%) | catalogued as COSV56730009; called by muse, mutect2
- MTUS2 | c.1072G>T p.D358Y | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.124); catalogued as COSV70913152, COSV70917231; called by muse, mutect2, varscan2
- MUC16 | c.41120G>T p.C13707F | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV66692988; called by muse, mutect2, varscan2
- MUC3A | c.7640C>A p.T2547N | Missense Mutation (SNP) | VAF 61/439 reads (14%) | SIFT deleterious, low confidence (0); catalogued as rs374517359; called by muse, mutect2, varscan2
- MYH13 | c.1787T>G p.L596R | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52831180; called by muse, mutect2, varscan2
- NDST4 | c.2199C>G p.D733E | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52122523; called by muse, mutect2, varscan2
- NMD3 | c.1193T>G p.V398G | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV63618736; called by muse, mutect2, varscan2
- SBF1 | c.4724C>T p.P1575L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs199779197; called by muse, mutect2, varscan2
- SERPINB5 | c.285C>A p.D95E | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV66975581; called by muse, mutect2, varscan2
- SLC2A7 | c.509C>T p.T170I | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as rs199637034, COSV68901866; called by muse, mutect2, varscan2
- SLC4A1 | c.1040A>T p.Y347F | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as COSV52260606; called by muse, mutect2, varscan2
- SLC4A4 | c.2828G>A p.R943H (on ENST00000264485 / NM_001098484.3; = p.R899H on NM_003759.4) | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762155173, COSV52626312, COSV52631395; called by muse, mutect2, varscan2
- SON | c.1571A>T p.H524L | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.014); catalogued as COSV51660026; called by muse, mutect2, varscan2
- TMC6 | c.1960A>T p.T654S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV59809439; called by muse, mutect2, varscan2
- TNFRSF9 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs765474605, COSV66349197; called by muse, mutect2, varscan2
- TP63 | c.274A>C p.S92R | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.798); catalogued as COSV53208406; called by muse, mutect2, varscan2
- TULP2 | c.721G>T p.A241S | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.038); catalogued as rs909229283, COSV55478442; called by muse, mutect2, varscan2
- USP6 | c.2332G>C p.D778H | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV51484611; called by muse, varscan2
- ZC3H7A | c.524G>C p.R175T | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63269867; called by muse, mutect2, varscan2
- ZNF625 | c.988C>G p.P330A | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV63242363; called by muse, mutect2, varscan2
- OR2L8 | c.690_707del p.E231_A236del | In Frame Del (DEL) | VAF 57/146 reads (39%) | called by mutect2, pindel, varscan2
- ZFPM1 | c.1124A>G p.Q375R | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- KCND2 | c.135G>T p.L45= | Silent (SNP) | VAF 82/374 reads (22%) | catalogued as COSV58574313, COSV58575553, COSV58583469; called by muse, mutect2, varscan2
- MUC16 | c.18786C>A p.I6262= | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as COSV67440988, COSV67471902; called by muse, varscan2
- RELN | c.9933C>A p.G3311= | Silent (SNP) | VAF 35/132 reads (27%) | catalogued as COSV59007517; called by muse, mutect2, varscan2
- SLC13A2 | c.1248G>A p.K416= | Silent (SNP) | VAF 73/133 reads (55%) | catalogued as COSV58995627; called by muse, mutect2, varscan2
- SULT2A1 | c.429A>G p.P143= | Silent (SNP) | VAF 34/77 reads (44%) | catalogued as rs535689179, COSV55765204; called by muse, mutect2, varscan2
- ZNF687 | c.2188C>A p.R730= | Silent (SNP) | VAF 35/72 reads (49%) | catalogued as COSV55018053; called by muse, mutect2, varscan2
- DCHS2 | n.2133G>C | RNA (SNP) | VAF 34/150 reads (23%) | catalogued as COSV59728602; called by muse, mutect2, varscan2
- OBSCN | c.4585+2585G>A | Intron (SNP) | VAF 9/54 reads (17%) | catalogued as rs528328336; called by muse, mutect2, varscan2
